Somatic mutation profile of tumor specimen TCGA-DB-A75O-01A (aliquot TCGA-DB-A75O-01A-11D-A32B-08) from TCGA case TCGA-DB-A75O, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 29.6 years (10,812 days).
Specimen TCGA-DB-A75O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 980fa1dd-b53e-423a-b78b-e422b6c48a07.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DB-A75O-10A (Blood Derived Normal), aliquot TCGA-DB-A75O-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ea8ae6af-f9e3-487b-8c5c-2313f0048b75

The open-access MAF lists 14 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Ins 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 30/82 reads (37%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by mutect2, varscan2
- AGAP3 | c.677C>A p.T226N (on ENST00000622464; = p.T262N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as COSV100103727, COSV58993847; called by muse, mutect2, varscan2
- FADS3 | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as rs759816565, COSV53877857, COSV53880410; called by muse, mutect2
- LRRTM1 | c.660C>G p.D220E | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as COSV99701876; called by muse, mutect2
- NALCN | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 104/323 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); catalogued as rs774880252, COSV51946575; called by muse, mutect2, varscan2
- NEURL1 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.348); catalogued as COSV100872660; called by muse, mutect2, varscan2
- OR5M10 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.012); catalogued as rs763236258, COSV73242390; called by muse, mutect2, varscan2
- RP1 | c.5387C>T p.T1796M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.125); catalogued as rs764959789, COSV55113518; called by muse, mutect2, varscan2
- TRPM7 | c.3328G>A p.V1110I | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.152); catalogued as rs1566974051, COSV100539413; called by muse, mutect2, varscan2
- TTN | c.48861T>A p.D16287E (on ENST00000591111; = p.D8863E on NM_003319.4) | Missense Mutation (SNP) | VAF 18/139 reads (13%) | PolyPhen benign (0.015); catalogued as COSV100595720; called by muse, mutect2, varscan2
- ZFYVE9 | c.1172A>G p.E391G | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV99819424; called by muse, mutect2, varscan2
- TCF12 | c.682_685dup p.D229Afs*9 | Frame Shift Ins (INS) | VAF 48/154 reads (31%) | called by mutect2, pindel, varscan2
- TP53 | c.363dup p.V122Cfs*27 | Frame Shift Ins (INS) | VAF 56/103 reads (54%) | called by mutect2, pindel, varscan2
- FAM234A | c.765C>T p.S255= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100055422; called by muse, mutect2, varscan2
